Somatic mutation profile of tumor specimen BLGSP-71-08-00059-01A (aliquot BLGSP-71-08-00059-01A-01D-A671-33) from CGCI case BLGSP-71-08-00059, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Vital status: Alive; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 7.3 years (2,684 days).
Specimen BLGSP-71-08-00059-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Abdomen; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 28b80499-412a-4ae1-8934-f4af0db03b07.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BLGSP-71-08-00059-10A (Blood Derived Normal), aliquot BLGSP-71-08-00059-10A-01D-A671-33; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a9cabbfa-85ea-4379-9b56-e913d3578687

The open-access MAF lists 8 somatic variants for this specimen: 4 protein-altering or splice-affecting, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, 5'Flank 2, Nonsense Mutation 1, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDX3X | c.1420C>T p.R474C (on ENST00000399959; = p.R475C on NM_001356.5) | Missense Mutation (SNP) | VAF 253/288 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1064794574, CM158049, COSV67864105; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXO11 | c.2173A>G p.N725D (on ENST00000403359 / NM_001190274.2; = p.N641D on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 198/457 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KMT2D | c.11300A>C p.Q3767P | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCBP1 | c.481C>T p.Q161* | Nonsense Mutation (SNP) | VAF 36/101 reads (36%) | called by muse, mutect2, varscan2
- DTX1 | c.-441G>A | 5'UTR (SNP) | VAF 10/28 reads (36%) | catalogued as COSV57495054; called by mutect2, varscan2
- FAS | c.568+1208_568+1209dup | Intron (INS) | VAF 106/285 reads (37%) | called by mutect2, pindel, varscan2
- MYC | chr8:127735890 G>A | 5'Flank (SNP) | VAF 20/51 reads (39%) | called by muse, mutect2, varscan2
- TSPOAP1 | chr17:58331926 G>C | 5'Flank (SNP) | VAF 141/355 reads (40%) | catalogued as rs193162831; called by muse, mutect2, varscan2
